Somatic mutation profile of tumor specimen ALCH-AELW-TTP1-A (aliquot ALCH-AELW-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AELW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.4 years (22,424 days).
Specimen ALCH-AELW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0de1443e-97d6-4f32-a462-f454b7576465.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AELW-NB1-A (Blood Derived Normal), aliquot ALCH-AELW-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51c440cb-020a-4fe3-8030-adef1b541d51

The open-access MAF lists 392 somatic variants for this specimen: 247 protein-altering or splice-affecting, 83 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 209, Silent 83, Intron 30, Nonsense Mutation 19, RNA 11, Splice Site 8, 5'UTR 7, 3'UTR 7, Frame Shift Del 6, 5'Flank 3, 3'Flank 3, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 22/112 reads (20%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.3153dup p.A1052Sfs*42 | Frame Shift Ins (INS) | VAF 31/266 reads (12%) | catalogued as rs775058588; called by mutect2, pindel, varscan2
- ACSM6 | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 33/366 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.288); catalogued as rs1368846171; called by muse, mutect2
- ACTN4 | c.1638C>A p.S546R | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV53146091; called by muse, mutect2, varscan2
- ADAM33 | c.1981G>C p.G661R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62936113; called by muse, mutect2, varscan2
- ADAMTSL3 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 52/409 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs139499552, COSV54436264; called by muse, mutect2, varscan2
- AIFM2 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV100325626; called by muse, mutect2
- AJUBA | c.769dup p.A257Gfs*49 | Frame Shift Ins (INS) | VAF 19/69 reads (28%) | catalogued as rs1327169406; called by mutect2, pindel, varscan2
- ALMS1 | c.3770A>G p.H1257R | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs770555189; called by muse, mutect2, varscan2
- ANKRD18A | c.1717G>C p.V573L | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.785); catalogued as rs1227515155; called by muse, mutect2
- AP002512.3 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 55/273 reads (20%) | catalogued as COSV99688085; called by muse, mutect2, varscan2
- APBA2 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as COSV68789154; called by muse, mutect2, varscan2
- ARID1B | c.4342C>T p.Q1448* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as rs1554235709; called by muse, mutect2, varscan2
- ASAH2 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.72); catalogued as rs578123995; called by muse, mutect2, varscan2
- ATP5IF1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs761008954; called by muse, mutect2
- BLVRA | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs138692014; called by muse, mutect2
- C9 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 68/888 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746167876; called by muse, mutect2
- CACNA1E | c.2293C>A p.H765N | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV62434934; called by muse, mutect2, varscan2
- CACNG3 | c.629A>C p.K210T | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV50067421; called by muse, mutect2, varscan2
- CEBPE | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779209834, COSV52830155; called by muse, mutect2, varscan2
- CELSR1 | c.6821C>T p.P2274L | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.955); catalogued as rs1353398992, COSV53082675; called by muse, mutect2, varscan2
- CHPF | c.1261G>C p.D421H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60534404; called by muse, mutect2
- CMYA5 | c.5741T>C p.V1914A | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as COSV71405600; called by muse, mutect2, varscan2
- CNTN5 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 93/871 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.06); catalogued as COSV54313004; called by muse, mutect2, varscan2
- COL11A1 | c.5006G>A p.G1669E | Missense Mutation (SNP) | VAF 57/474 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV100617896; called by muse, mutect2, varscan2
- COL20A1 | c.3529G>T p.G1177* | Nonsense Mutation (SNP) | VAF 20/112 reads (18%) | catalogued as COSV100491461; called by muse, mutect2, varscan2
- CSMD3 | c.10690C>T p.H3564Y (on ENST00000297405 / NM_001363185.1; = p.H3395Y on NM_052900.3) | Missense Mutation (SNP) | VAF 52/438 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs760263475; called by muse, mutect2, varscan2
- CSNK1G1 | c.470C>G p.S157* | Nonsense Mutation (SNP) | VAF 50/323 reads (15%) | catalogued as COSV57311968; called by muse, mutect2, varscan2
- CTCF | c.219G>T p.M73I | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV50497724; called by muse, mutect2
- DIS3 | c.1945A>G p.I649V | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.264); catalogued as rs377447325; called by muse, mutect2, varscan2
- DNAH11 | c.4093A>G p.K1365E | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768748144; called by muse, mutect2, varscan2
- DNAH17 | c.1730T>C p.L577P | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1568258928; called by muse, mutect2, varscan2
- EFNA1 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV100310461; called by muse, mutect2, varscan2
- ESX1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1162286055, COSV65425012; called by mutect2, varscan2
- FAM135B | c.2132G>T p.R711L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV99428707; called by muse, mutect2, varscan2
- FAM20C | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1319019323; called by muse, mutect2, varscan2
- FAP | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs772284412, COSV51859937; called by muse, mutect2, varscan2
- FAT2 | c.1369del p.L457Sfs*24 | Frame Shift Del (DEL) | VAF 34/142 reads (24%) | catalogued as COSV55815079; called by mutect2, pindel, varscan2
- FAT4 | c.2276A>G p.Y759C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1412195554; called by muse, mutect2, varscan2
- FBXO25 | c.338C>G p.S113* (on ENST00000382824 / NM_183421.2; = p.S46* on NM_012173.3) | Nonsense Mutation (SNP) | VAF 16/200 reads (8%) | catalogued as COSV99366822; called by muse, mutect2
- FLT1 | c.1182C>A p.D394E | Missense Mutation (SNP) | VAF 47/439 reads (11%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.969); catalogued as rs775108754, COSV56735778; called by muse, mutect2, varscan2
- FMO4 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100882036, COSV63001947; called by muse, mutect2
- FOXI2 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV59094319; called by muse, mutect2, varscan2
- FRY | c.1378C>A p.Q460K | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV66582030; called by muse, mutect2, varscan2
- FSIP2 | c.16468C>G p.P5490A | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs773711098; called by muse, mutect2, varscan2
- GRM4 | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0.01); catalogued as rs1203093700; called by muse, mutect2, varscan2
- H2AC20 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58611399, COSV58611757; called by muse, mutect2
- HECW2 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs1273453024; called by muse, mutect2, varscan2
- HEPH | c.757G>T p.A253S (on ENST00000343002; = p.A307S on NM_138737.5) | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs780052001; called by muse, mutect2, varscan2
- HPSE | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 62/367 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60986997; called by muse, mutect2, varscan2
- IGDCC3 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.667); catalogued as rs1306680153; called by muse, mutect2, varscan2
- IKBKB | c.2112G>C p.K704N | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100645818; called by muse, mutect2
- IKZF2 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs753031929, COSV59580699; called by muse, mutect2, varscan2
- IL22 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 100/300 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100048851; called by muse, mutect2, varscan2
- KCNH1 | c.2914G>C p.E972Q (on ENST00000271751 / NM_172362.3; = p.E945Q on NM_002238.4) | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV99657511; called by muse, mutect2
- KCNMA1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.781); catalogued as rs202188099; called by muse, mutect2, varscan2
- KIFAP3 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs763019177, COSV63035911; called by muse, mutect2
- LILRA2 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 34/454 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs996076236; called by muse, mutect2
- LRP1B | c.4241G>C p.R1414T | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67267690, COSV67284563; called by muse, mutect2
- LRRC14B | c.1453C>G p.Q485E | Missense Mutation (SNP) | VAF 20/440 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1200424803; called by muse, mutect2
- LRRIQ3 | c.947C>A p.P316Q | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100599440; called by muse, mutect2, varscan2
- LRRK2 | c.2500+2T>A p.X834_splice | Splice Site (SNP) | VAF 72/201 reads (36%) | catalogued as COSV100109905; called by muse, mutect2, varscan2
- LRRN2 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781028138, COSV65783362; called by muse, mutect2, varscan2
- LYST | c.9304G>A p.D3102N | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.71); catalogued as COSV101087910; called by muse, mutect2
- MICAL2 | c.1348C>G p.Q450E | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV56321656; called by muse, mutect2, varscan2
- MYBL1 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as rs757999984; called by muse, mutect2
- MYO10 | c.4160G>C p.R1387T | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as COSV99944745; called by muse, mutect2, varscan2
- NAA11 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1417211253; called by muse, mutect2, varscan2
- NAV2 | c.4919C>T p.S1640F | Missense Mutation (SNP) | VAF 35/338 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60656047; called by muse, mutect2, varscan2
- NCOA2 | c.3766C>A p.Q1256K | Missense Mutation (SNP) | VAF 79/495 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.824); catalogued as COSV51221919; called by muse, mutect2, varscan2
- NOD2 | c.1780G>T p.G594W | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100318054; called by muse, mutect2, varscan2
- NPAP1 | c.1421del p.G474Vfs*15 | Frame Shift Del (DEL) | VAF 37/229 reads (16%) | catalogued as COSV61509891; called by mutect2, pindel, varscan2
- OBSCN | c.4252G>A p.G1418R | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375814608; called by muse, mutect2, varscan2
- OR2B6 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776516996; called by muse, mutect2, varscan2
- OR52I2 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 66/296 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.109); catalogued as rs1260586857; called by muse, varscan2
- OR5A1 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs774688917, COSV57376384; called by muse, mutect2, varscan2
- P3H1 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs772144247, COSV52538553; called by muse, mutect2, varscan2
- PCDH15 | c.4837G>A p.E1613K | Missense Mutation (SNP) | VAF 161/437 reads (37%) | SIFT tolerated, low confidence (0.22); catalogued as rs1401920789; called by muse, mutect2, varscan2
- PCDHGB7 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.378); catalogued as rs755798236, COSV99548670; called by muse, mutect2
- PRRG1 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.17); catalogued as rs782732925, COSV66158894; called by muse, mutect2
- RIMS2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs538898351; called by muse, mutect2
- SAFB | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as COSV52650863; called by muse, mutect2, varscan2
- SAMD7 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 72/429 reads (17%) | catalogued as rs778339771, COSV100156950; called by muse, mutect2, varscan2
- SCRIB | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1384682740, COSV57589784; called by muse, varscan2
- SCUBE1 | c.2789C>T p.S930L | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1174496305, COSV62612783; called by muse, mutect2
- SGCD | c.503C>A p.A168E (on ENST00000435422 / NM_001128209.2; = p.A169E on NM_000337.5) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.103); catalogued as rs876658001, COSV61914545; called by muse, mutect2, varscan2
- SHARPIN | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV59363075; called by muse, mutect2
- SIRPA | c.454G>T p.V152L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs143335460, COSV100605123; called by muse, mutect2, varscan2
- SRRM2 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV57074778; called by muse, mutect2
- TANC1 | c.2389G>T p.A797S | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV55087320; called by muse, mutect2, varscan2
- TERF2 | c.1375G>A p.V459I | Missense Mutation (SNP) | VAF 51/341 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as rs781201377; called by muse, mutect2, varscan2
- TG | c.8017G>C p.E2673Q | Missense Mutation (SNP) | VAF 77/622 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.787); catalogued as COSV99602234; called by muse, mutect2, varscan2
- TIMP3 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 106/352 reads (30%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as rs144942953; called by muse, mutect2, varscan2
- TLDC2 | c.370A>T p.I124F | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1201213281; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs747644318, COSV54871298, COSV99621730; called by muse, mutect2, varscan2
- TRIM51 | c.731T>G p.L244R | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs761828481; called by muse, mutect2, varscan2
- TRPA1 | c.693C>A p.H231Q | Missense Mutation (SNP) | VAF 118/531 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100084398; called by muse, mutect2, varscan2
- UGGT2 | c.1293G>A p.W431* | Nonsense Mutation (SNP) | VAF 76/277 reads (27%) | catalogued as rs749940983; called by muse, mutect2, varscan2
- USH2A | c.8776G>C p.E2926Q | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV56393642; called by muse, mutect2
- WWTR1 | c.1159G>C p.E387Q | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.365); catalogued as COSV99053819; called by muse, mutect2, varscan2
- ZNF214 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs1324618076; called by muse, mutect2, varscan2
- ZNF257 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 51/207 reads (25%) | catalogued as COSV71306934; called by muse, mutect2, varscan2
- ZNF485 | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.373); catalogued as COSV62424586; called by muse, mutect2, varscan2
- ADAMTS18 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP12 | c.1182G>C p.E394D | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- AKR1C4 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- AMBN | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 78/340 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.666); called by mutect2, varscan2
- ANKRD11 | c.7114C>T p.R2372C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by mutect2, varscan2
- ANKRD30A | c.572dup p.L191Ffs*12 (on ENST00000611781; = p.L135Ffs*12 on NM_052997.2) | Frame Shift Ins (INS) | VAF 25/129 reads (19%) | called by mutect2, pindel, varscan2
- ANO4 | c.2237G>T p.R746L (on ENST00000392977 / NM_001286615.2; = p.R711L on NM_178826.4) | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ASH1L | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- ASH1L | c.634G>T p.G212* | Nonsense Mutation (SNP) | VAF 35/173 reads (20%) | called by muse, mutect2, varscan2
- ATP13A3 | c.1855G>C p.E619Q | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- BANP | c.907G>T p.D303Y (on ENST00000286122; = p.D272Y on NM_017869.4) | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BIRC6 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, varscan2
- BIRC6 | c.2950C>G p.L984V | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.018); called by muse, mutect2
- BSN | c.7371_7390del p.L2458Afs*18 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel
- C18orf63 | c.979-1G>A p.X327_splice | Splice Site (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- CACNA1E | c.2292C>A p.S764R | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- CACNA2D3 | c.1087C>G p.Q363E | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC191 | c.1796T>G p.V599G | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- CCDC27 | c.665G>T p.C222F | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC88B | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CCM2L | c.1690del p.D564Tfs*23 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- CDC27 | c.994G>T p.V332F | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CDK12 | c.2508C>G p.I836M | Missense Mutation (SNP) | VAF 58/338 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CHIA | c.586G>C p.E196Q (on ENST00000343320; = p.E88Q on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CLMN | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.268); called by muse, mutect2
- CNIH2 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 61/285 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- COL6A3 | c.8536A>T p.K2846* | Nonsense Mutation (SNP) | VAF 42/284 reads (15%) | called by muse, mutect2, varscan2
- CSMD3 | c.5959G>T p.E1987* (on ENST00000297405 / NM_001363185.1; = p.E1883* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 90/481 reads (19%) | called by muse, mutect2, varscan2
- CSMD3 | c.2438C>A p.A813D (on ENST00000297405 / NM_001363185.1; = p.A709D on NM_052900.3) | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSTL1 | c.426A>T p.R142S | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CTH | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 46/436 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- CWH43 | c.1258G>C p.G420R | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- DAGLB | c.494A>T p.Y165F | Missense Mutation (SNP) | VAF 100/512 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- DARS1 | c.164A>T p.K55I | Missense Mutation (SNP) | VAF 93/459 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF4L2 | c.630G>T p.L210F | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- DDIT4 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- DOCK10 | c.5008C>G p.Q1670E | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- DSCC1 | c.687C>G p.C229W | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- DSTYK | c.2355G>C p.L785= | Splice Region (SNP) | VAF 31/228 reads (14%) | called by muse, mutect2, varscan2
- EBF3 | c.853G>T p.G285C (on ENST00000355311 / NM_001375392.1; = p.G276C on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMX2 | c.440A>T p.H147L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ERICH3 | c.1361C>G p.A454G | Missense Mutation (SNP) | VAF 47/410 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- FBXW7 | c.1520T>G p.V507G (on ENST00000281708 / NM_001349798.2; = p.V427G on NM_018315.5) | Missense Mutation (SNP) | VAF 122/478 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABPB1 | c.128A>G p.H43R | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GCLC | c.585C>G p.I195M (on ENST00000643939; = p.I193M on NM_001498.4) | Missense Mutation (SNP) | VAF 95/541 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GOLGA3 | c.4033G>T p.D1345Y | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GRM3 | c.1710C>G p.I570M | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- GSK3B | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- HCN1 | c.1730C>A p.P577Q | Missense Mutation (SNP) | VAF 190/638 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEATR5B | c.3805C>G p.H1269D | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HMCN1 | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 61/433 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- HNRNPA0 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2
- HUWE1 | c.7126G>A p.E2376K | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- INO80 | c.2590C>G p.L864V | Missense Mutation (SNP) | VAF 42/450 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- IQGAP3 | c.2431C>G p.L811V | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.033); called by muse, mutect2
- ITGA10 | c.2233G>A p.D745N | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2
- ITGB1BP2 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- KBTBD4 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- KBTBD4 | c.39G>C p.E13D | Missense Mutation (SNP) | VAF 75/458 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCNIP4 | c.168C>A p.S56R | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- KDM5C | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KIF27 | c.1915C>T p.H639Y | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- KMT2D | c.5581G>T p.E1861* | Nonsense Mutation (SNP) | VAF 83/253 reads (33%) | called by muse, mutect2, varscan2
- LAMB3 | c.3485A>C p.N1162T | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LAMC3 | c.2411C>A p.P804H | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- LGR6 | c.289C>T p.L97F (on ENST00000367278 / NM_001017403.1; = p.L45F on NM_021636.3) | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LPIN2 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 68/433 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC41 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LTK | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- MACF1 | c.20778G>C p.E6926D (on ENST00000372915; = p.E4971D on NM_012090.5) | Missense Mutation (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- MARCHF10 | c.803C>A p.S268* | Nonsense Mutation (SNP) | VAF 133/364 reads (37%) | called by muse, mutect2, varscan2
- ME2 | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- MFSD6L | c.914del p.L305Wfs*9 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | called by mutect2, pindel, varscan2
- MIOS | c.1122A>T p.L374F | Missense Mutation (SNP) | VAF 69/327 reads (21%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- MMP27 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 18/339 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.786); called by muse, mutect2
- MUC4 | c.14584G>C p.E4862Q (on ENST00000463781 / NM_018406.7; = p.E626Q on NM_004532.6) | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- MYBPC1 | c.1652G>A p.G551E (on ENST00000550270 / NM_206820.2; = p.G576E on NM_002465.4) | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYBPC3 | c.2741C>G p.S914* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- NAALADL2 | c.820-1G>T p.X274_splice | Splice Site (SNP) | VAF 34/150 reads (23%) | called by muse, mutect2, varscan2
- NKX2-4 | c.857C>A p.P286Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NLRP14 | c.2147A>T p.D716V | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.049); called by muse, mutect2
- NLRP5 | c.899T>A p.V300E | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2
- NPSR1 | c.1011C>G p.I337M | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.157); called by muse, mutect2
- NRBP2 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- NRM | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NTSR1 | c.847C>A p.H283N | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- OR2T3 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 94/288 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- OR4C6 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 75/321 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- OR4Q2 | c.677G>C p.R226P | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- OR51Q1 | c.148G>C p.V50L | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2
- OR6X1 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- OSBPL9 | c.318+2_318+5del p.X106_splice | Splice Site (DEL) | VAF 23/195 reads (12%) | called by mutect2, pindel, varscan2
- OSTN | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- OTOF | c.1724T>A p.V575E | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PAX6 | c.1154C>A p.P385Q | Missense Mutation (SNP) | VAF 96/332 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PIGK | c.148-2A>T p.X50_splice | Splice Site (SNP) | VAF 20/203 reads (10%) | called by muse, mutect2, varscan2
- PIWIL1 | c.1705G>C p.D569H | Missense Mutation (SNP) | VAF 108/315 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNPLA5 | c.648C>G p.I216M | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2
- POLR1B | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PPP1R2 | c.401G>C p.R134P | Missense Mutation (SNP) | VAF 73/271 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- PRUNE2 | c.8854_8863del p.M2953Kfs*4 | Frame Shift Del (DEL) | VAF 35/209 reads (17%) | called by mutect2, pindel, varscan2
- RAB11FIP4 | c.526G>C p.D176H | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, mutect2
- RAD50 | c.925C>G p.H309D | Missense Mutation (SNP) | VAF 52/478 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RADIL | c.1905G>T p.Q635H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RARS1 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 27/288 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.2); called by muse, mutect2
- RASGRP3 | c.1471C>A p.P491T (on ENST00000402538 / NM_001349975.2; = p.P490T on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/254 reads (7%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.879); called by muse, mutect2
- RBBP6 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 32/472 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); called by muse, mutect2
- RCC1 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); called by muse, mutect2
- RETREG1 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RFX3 | c.1064G>T p.S355I | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIM1 | c.348G>C p.Q116H | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIRPB2 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- SLC44A5 | c.769T>G p.W257G | Missense Mutation (SNP) | VAF 60/377 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SP110 | c.1957-1G>C p.X653_splice | Splice Site (SNP) | VAF 99/540 reads (18%) | called by muse, mutect2, varscan2
- SPACA1 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATA16 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 81/348 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SRP68 | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2, varscan2
- TAOK3 | c.503C>G p.S168C | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- TAS2R20 | c.641A>G p.K214R | Missense Mutation (SNP) | VAF 21/334 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.364); called by muse, mutect2
- TBC1D32 | c.1576C>T p.Q526* | Nonsense Mutation (SNP) | VAF 43/402 reads (11%) | called by muse, mutect2, varscan2
- TCN1 | c.937+1G>T p.X313_splice | Splice Site (SNP) | VAF 30/295 reads (10%) | called by muse, mutect2, varscan2
- TDRD1 | c.662C>G p.S221C | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- TDRD5 | c.1889G>T p.G630V | Missense Mutation (SNP) | VAF 46/455 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TLE4 | c.1891G>T p.G631C | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TM9SF3 | c.898C>G p.Q300E | Missense Mutation (SNP) | VAF 26/355 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2
- TRAPPC9 | c.2597C>G p.P866R | Missense Mutation (SNP) | VAF 115/460 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- TRGC1 | c.431T>G p.L144R | Missense Mutation (SNP) | VAF 159/1195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TRIML1 | c.97C>A p.H33N | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPA1 | c.2736G>T p.M912I | Missense Mutation (SNP) | VAF 129/561 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- TTN | c.68293G>A p.G22765R (on ENST00000591111; = p.G15341R on NM_003319.4) | Missense Mutation (SNP) | VAF 40/230 reads (17%) | PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.68291A>G p.E22764G (on ENST00000591111; = p.E15340G on NM_003319.4) | Missense Mutation (SNP) | VAF 40/228 reads (18%) | PolyPhen possibly damaging (0.776); called by muse, mutect2
- TTN | c.28877C>A p.P9626H (on ENST00000591111; = p.P8699H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/364 reads (9%) | PolyPhen benign (0.346); called by muse, mutect2
- UNC80 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- UNC80 | c.1872C>A p.D624E | Missense Mutation (SNP) | VAF 52/332 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- USH2A | c.5312G>C p.S1771T | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.138); called by muse, mutect2
- USP31 | c.3002C>A p.S1001Y | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- WASHC5 | c.1676A>T p.Q559L | Missense Mutation (SNP) | VAF 88/527 reads (17%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- XIRP2 | c.814G>T p.G272* (on ENST00000628543; = p.G447* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 38/231 reads (16%) | called by muse, mutect2, varscan2
- XKR4 | c.1583G>T p.C528F | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZBTB33 | c.1858G>T p.D620Y | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- ZDHHC13 | c.520-2A>T p.X174_splice | Splice Site (SNP) | VAF 20/151 reads (13%) | called by muse, mutect2, varscan2
- ZNF84 | c.1768C>T p.Q590* | Nonsense Mutation (SNP) | VAF 33/354 reads (9%) | called by muse, mutect2
- ZSCAN18 | c.92A>T p.Q31L | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- ZSCAN31 | c.742T>G p.F248V | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACADL | c.852C>A p.I284= | Silent (SNP) | VAF 58/452 reads (13%) | catalogued as COSV52055334; called by muse, mutect2, varscan2
- AKAP13 | c.1182A>G p.V394= | Silent (SNP) | VAF 75/327 reads (23%) | catalogued as rs1009469550; called by muse, mutect2, varscan2
- APOB | c.13080T>C p.N4360= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as rs757044199; called by muse, mutect2, varscan2
- APOB | c.5136T>C p.S1712= | Silent (SNP) | VAF 24/114 reads (21%) | called by muse, mutect2, varscan2
- ATP13A3 | c.2055G>C p.V685= | Silent (SNP) | VAF 74/435 reads (17%) | called by muse, mutect2, varscan2
- ATP2A1 | c.450C>T p.I150= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as rs781369773, COSV63922004; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- B3GNT2 | c.1116G>C p.L372= | Silent (SNP) | VAF 50/224 reads (22%) | called by muse, mutect2, varscan2
- B4GALT2 | c.894C>T p.R298= | Silent (SNP) | VAF 36/189 reads (19%) | called by muse, mutect2, varscan2
- BRWD3 | c.2634A>C p.T878= | Silent (SNP) | VAF 33/276 reads (12%) | called by muse, mutect2, varscan2
- CBLN1 | c.517C>A p.R173= | Silent (SNP) | VAF 38/246 reads (15%) | called by muse, mutect2, varscan2
- CC2D1B | c.2109G>A p.L703= | Silent (SNP) | VAF 29/247 reads (12%) | called by muse, mutect2, varscan2
- CSMD3 | c.9540C>A p.A3180= (on ENST00000297405 / NM_001363185.1; = p.A3011= on NM_052900.3) | Silent (SNP) | VAF 136/527 reads (26%) | called by muse, mutect2, varscan2
- CTNNA2 | c.1956G>A p.R652= | Silent (SNP) | VAF 26/264 reads (10%) | catalogued as COSV58171054; called by muse, mutect2, varscan2
- CUBN | c.10164C>T p.F3388= | Silent (SNP) | VAF 39/432 reads (9%) | catalogued as COSV100912648; called by muse, mutect2
- DCP1B | c.1227T>C p.N409= | Silent (SNP) | VAF 70/283 reads (25%) | called by muse, mutect2, varscan2
- DIAPH1 | c.1254C>G p.L418= | Silent (SNP) | VAF 44/340 reads (13%) | called by muse, mutect2, varscan2
- DIPK1C | c.1161C>G p.V387= | Silent (SNP) | VAF 15/147 reads (10%) | called by muse, mutect2
- DNAJC22 | c.783G>A p.A261= | Silent (SNP) | VAF 22/279 reads (8%) | catalogued as rs202077468; called by muse, mutect2
- EFHC1 | c.735C>T p.F245= | Silent (SNP) | VAF 92/595 reads (15%) | called by muse, mutect2, varscan2
- EXOC8 | c.1251A>G p.Q417= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs1383004943; called by muse, mutect2, varscan2
- FABP4 | c.135G>A p.V45= | Silent (SNP) | VAF 38/232 reads (16%) | called by muse, mutect2, varscan2
- FER1L6 | c.987C>A p.G329= | Silent (SNP) | VAF 66/341 reads (19%) | called by muse, mutect2, varscan2
- GLRB | c.978G>A p.V326= | Silent (SNP) | VAF 44/329 reads (13%) | catalogued as COSV100029759; called by muse, mutect2, varscan2
- GPR160 | c.525T>C p.P175= | Silent (SNP) | VAF 43/352 reads (12%) | catalogued as rs1559995625; called by muse, mutect2, varscan2
- GRIK3 | c.198C>A p.I66= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV66145725; called by muse, mutect2, varscan2
- H3C1 | c.381C>T p.L127= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as rs375098086; called by muse, mutect2, varscan2
- HSF1 | c.591G>A p.V197= | Silent (SNP) | VAF 10/231 reads (4%) | called by muse, mutect2
- IREB2 | c.874C>T p.L292= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV51926188; called by muse, varscan2
- IRX2 | c.135C>T p.F45= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs1435224659; called by muse, mutect2, varscan2
- ITPR2 | c.4029G>C p.L1343= | Silent (SNP) | VAF 24/512 reads (5%) | called by muse, mutect2
- LAMA2 | c.9054G>C p.G3018= | Silent (SNP) | VAF 143/444 reads (32%) | called by muse, mutect2, varscan2
- LGALS3 | c.489C>T p.F163= | Silent (SNP) | VAF 32/212 reads (15%) | called by muse, mutect2, varscan2
- MMS22L | c.3021C>T p.I1007= | Silent (SNP) | VAF 15/138 reads (11%) | called by muse, mutect2, varscan2
- MS4A14 | c.441A>T p.I147= | Silent (SNP) | VAF 48/518 reads (9%) | called by muse, mutect2
- NES | c.3030C>T p.G1010= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs1454642034; called by muse, mutect2
- NLRP2 | c.2193G>A p.Q731= | Silent (SNP) | VAF 166/376 reads (44%) | called by muse, mutect2, varscan2
- NUP160 | c.1086A>C p.A362= | Silent (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2
- OR1M1 | c.564G>T p.S188= | Silent (SNP) | VAF 64/210 reads (30%) | called by muse, mutect2, varscan2
- OR4A16 | c.420C>A p.I140= | Silent (SNP) | VAF 40/434 reads (9%) | catalogued as COSV59043219; called by muse, mutect2
- OR51B4 | c.624T>A p.A208= | Silent (SNP) | VAF 56/214 reads (26%) | called by muse, mutect2, varscan2
- OR52I2 | c.498C>T p.L166= | Silent (SNP) | VAF 60/288 reads (21%) | catalogued as rs1420787124; called by muse, varscan2
- OR52L1 | c.243G>T p.L81= | Silent (SNP) | VAF 81/338 reads (24%) | catalogued as rs772064651; called by muse, mutect2, varscan2
- OR8A1 | c.9A>G p.A3= | Silent (SNP) | VAF 29/102 reads (28%) | called by mutect2, varscan2
- OSBPL2 | c.1182G>A p.E394= (on ENST00000313733 / NM_144498.4; = p.E382= on NM_014835.4) | Silent (SNP) | VAF 31/167 reads (19%) | called by muse, mutect2, varscan2
- PARP15 | c.378G>A p.L126= | Silent (SNP) | VAF 68/341 reads (20%) | catalogued as rs1220141764; called by muse, mutect2, varscan2
- PCDHB15 | c.1530C>T p.N510= | Silent (SNP) | VAF 37/217 reads (17%) | catalogued as rs1554292103, COSV50895175; called by muse, mutect2, varscan2
- POTEI | c.825A>T p.P275= | Silent (SNP) | VAF 33/293 reads (11%) | called by mutect2, varscan2
- POTEJ | c.714A>T p.P238= | Silent (SNP) | VAF 19/127 reads (15%) | called by mutect2, varscan2
- PRDM6 | c.960G>C p.S320= | Silent (SNP) | VAF 23/288 reads (8%) | called by muse, mutect2
- PREPL | c.1953A>G p.K651= | Silent (SNP) | VAF 16/296 reads (5%) | called by muse, mutect2
- PSMD1 | c.1950C>T p.Y650= | Silent (SNP) | VAF 35/383 reads (9%) | catalogued as rs1159016013, COSV100433484; called by muse, mutect2
- RASGRP4 | c.1599C>A p.S533= | Silent (SNP) | VAF 22/106 reads (21%) | called by muse, mutect2, varscan2
- RFX6 | c.2475C>A p.I825= | Silent (SNP) | VAF 114/343 reads (33%) | called by muse, mutect2, varscan2
- SBK2 | c.51G>A p.E17= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs1471575271; called by muse, mutect2, varscan2
- SIGLEC1 | c.4458G>A p.R1486= | Silent (SNP) | VAF 58/223 reads (26%) | called by muse, mutect2, varscan2
- SIGLEC12 | c.1787G>A p.*596= (on ENST00000291707 / NM_053003.4; = p.*478= on NM_033329.2) | Silent (SNP) | VAF 37/144 reads (26%) | called by muse, mutect2, varscan2
- SLC35D1 | c.192C>T p.L64= | Silent (SNP) | VAF 13/152 reads (9%) | catalogued as rs753103405, COSV52433644; called by muse, mutect2
- SNAPC4 | c.999C>T p.C333= | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- SYNE1 | c.19338G>A p.E6446= (on ENST00000367255 / NM_182961.4; = p.E6375= on NM_033071.3) | Silent (SNP) | VAF 73/376 reads (19%) | catalogued as COSV54902872, COSV54940888; called by muse, mutect2, varscan2
- TAF2 | c.429C>A p.V143= | Silent (SNP) | VAF 38/512 reads (7%) | called by muse, mutect2
- TBX22 | c.936C>G p.G312= | Silent (SNP) | VAF 119/256 reads (46%) | catalogued as COSV64786596; called by muse, mutect2, varscan2
- TBXT | c.546C>T p.I182= | Silent (SNP) | VAF 84/466 reads (18%) | called by muse, mutect2, varscan2
- TCIRG1 | c.582C>A p.L194= | Silent (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- TDRD5 | c.1890A>T p.G630= | Silent (SNP) | VAF 47/459 reads (10%) | called by muse, mutect2, varscan2
- TEX15 | c.1698G>T p.V566= (on ENST00000256246; = p.V949= on NM_001350162.2) | Silent (SNP) | VAF 31/259 reads (12%) | called by muse, mutect2, varscan2
- TGFA | c.114A>G p.A38= | Silent (SNP) | VAF 35/128 reads (27%) | called by muse, mutect2, varscan2
- TMEM252 | c.201T>A p.T67= | Silent (SNP) | VAF 51/195 reads (26%) | catalogued as COSV101051107, COSV66065913; called by muse, mutect2, varscan2
- TMEM60 | c.393G>C p.V131= | Silent (SNP) | VAF 7/40 reads (18%) | called by mutect2, varscan2
- TMEM70 | c.501C>T p.V167= | Silent (SNP) | VAF 193/830 reads (23%) | called by muse, mutect2, varscan2
- TSNARE1 | c.1341G>A p.V447= | Silent (SNP) | VAF 42/196 reads (21%) | called by muse, mutect2, varscan2
- TTLL7 | c.1591C>T p.L531= | Silent (SNP) | VAF 23/179 reads (13%) | called by muse, varscan2
- TTN | c.100140C>A p.G33380= (on ENST00000591111; = p.G25956= on NM_003319.4) | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as rs757125254, COSV59892177; called by muse, mutect2, varscan2
- UBR5 | c.6553C>T p.L2185= | Silent (SNP) | VAF 20/296 reads (7%) | called by muse, mutect2
- UMOD | c.1083G>A p.L361= | Silent (SNP) | VAF 34/303 reads (11%) | called by muse, mutect2
- USH2A | c.14532G>T p.T4844= | Silent (SNP) | VAF 24/172 reads (14%) | called by muse, mutect2, varscan2
- XPR1 | c.1029C>T p.P343= | Silent (SNP) | VAF 38/220 reads (17%) | called by muse, mutect2, varscan2
- ZBTB10 | c.2100G>A p.L700= (on ENST00000430430; = p.L676= on NM_023929.4) | Silent (SNP) | VAF 51/249 reads (20%) | called by muse, mutect2, varscan2
- ZFHX4 | c.8394C>A p.T2798= | Silent (SNP) | VAF 39/207 reads (19%) | called by muse, mutect2, varscan2
- ZNF280D | c.2361T>C p.N787= | Silent (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- ZNF283 | c.1671C>T p.H557= | Silent (SNP) | VAF 36/167 reads (22%) | called by muse, mutect2, varscan2
- ZNF324B | c.1224G>A p.Q408= | Silent (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- ZNF804B | c.1698T>C p.Y566= | Silent (SNP) | VAF 26/182 reads (14%) | called by muse, mutect2, varscan2
- ZSCAN5C | c.556C>T p.L186= | Silent (SNP) | VAF 39/95 reads (41%) | called by muse, mutect2, varscan2
- ACY1 | c.160-14del | Intron (DEL) | VAF 36/178 reads (20%) | called by mutect2, pindel, varscan2
- ADAM28 | c.1567+50C>T | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- AGAP12P | n.1996G>T | RNA (SNP) | VAF 58/562 reads (10%) | called by muse, varscan2
- AL353804.7 | chrX:73851566 C>T | 3'Flank (SNP) | VAF 127/362 reads (35%) | called by muse, mutect2, varscan2
- AL627230.3 | c.75+167G>A | Intron (SNP) | VAF 15/120 reads (13%) | catalogued as rs1248306015; called by mutect2, varscan2
- BCHE | c.-24T>C | 5'UTR (SNP) | VAF 35/214 reads (16%) | called by muse, mutect2, varscan2
- C12orf76 | n.335G>A | RNA (SNP) | VAF 37/328 reads (11%) | called by muse, mutect2, varscan2
- C7orf66 | n.130del | RNA (DEL) | VAF 57/239 reads (24%) | called by mutect2, pindel, varscan2
- CDH18 | c.1630+72C>G | Intron (SNP) | VAF 51/268 reads (19%) | catalogued as rs1297195143, COSV56908659; called by muse, mutect2, varscan2
- CLCN5 | c.17-32511C>T | Intron (SNP) | VAF 9/47 reads (19%) | catalogued as COSV65803701; called by muse, mutect2
- CTTN | c.457+17G>A | Intron (SNP) | VAF 39/145 reads (27%) | called by muse, mutect2, varscan2
- EFHC1 | c.*2215del | 3'UTR (DEL) | VAF 57/189 reads (30%) | called by mutect2, pindel, varscan2
- EIF4A2 | c.999+100A>G | Intron (SNP) | VAF 54/276 reads (20%) | catalogued as rs1408574781; called by muse, mutect2, varscan2
- EMX1 | c.705+985A>T | Intron (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- EXTL2 | c.-41G>A | 5'UTR (SNP) | VAF 9/88 reads (10%) | catalogued as rs1483087123; called by muse, mutect2, varscan2
- FGFR3 | c.*258C>A | 3'UTR (SNP) | VAF 13/39 reads (33%) | catalogued as COSV104368259; called by muse, mutect2, varscan2
- GDNF | c.*49G>C | 3'UTR (SNP) | VAF 35/380 reads (9%) | called by muse, mutect2
- HGSNAT | c.1542+17C>G | Intron (SNP) | VAF 23/268 reads (9%) | called by muse, mutect2
- INTS9 | c.1801-23C>T | Intron (SNP) | VAF 30/201 reads (15%) | called by muse, mutect2, varscan2
- KALRN | c.4929+8474C>G | Intron (SNP) | VAF 22/198 reads (11%) | called by muse, mutect2, varscan2
- KBTBD4 | c.696+24G>A | Intron (SNP) | VAF 66/406 reads (16%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.105C>G | RNA (SNP) | VAF 10/116 reads (9%) | catalogued as COSV99069016; called by muse, mutect2
- LENG8 | c.*1980C>A | 3'UTR (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- MEGF11 | c.2711-2912C>T | Intron (SNP) | VAF 26/141 reads (18%) | catalogued as rs1235240511; called by muse, mutect2, varscan2
- MIR380 | n.17G>A | RNA (SNP) | VAF 37/117 reads (32%) | called by muse, mutect2, varscan2
- MPI | c.1054-9C>T | Intron (SNP) | VAF 31/396 reads (8%) | catalogued as rs765561722; called by muse, mutect2
- MUC19 | n.5184G>A | RNA (SNP) | VAF 69/232 reads (30%) | called by muse, mutect2, varscan2
- MUC19 | n.5185A>T | RNA (SNP) | VAF 70/233 reads (30%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-719G>A | Intron (SNP) | VAF 22/234 reads (9%) | called by muse, mutect2
- NAALAD2 | c.1278+15G>C | Intron (SNP) | VAF 99/369 reads (27%) | called by muse, mutect2, varscan2
- NAXD | c.*143A>G | 3'UTR (SNP) | VAF 36/228 reads (16%) | catalogued as rs1451017351; called by muse, mutect2, varscan2
- NDUFS3 | c.68-44C>T | Intron (SNP) | VAF 30/179 reads (17%) | called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.1074G>C | RNA (SNP) | VAF 29/186 reads (16%) | called by muse, mutect2, varscan2
- NME6 | c.90+49G>T | Intron (SNP) | VAF 66/271 reads (24%) | called by muse, mutect2, varscan2
- OR4N3P | n.330G>A | RNA (SNP) | VAF 68/391 reads (17%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157400 C>A | 3'Flank (SNP) | VAF 84/313 reads (27%) | called by muse, mutect2, varscan2
- PDE2A | c.72-15539C>A | Intron (SNP) | VAF 73/203 reads (36%) | called by muse, mutect2, varscan2
- PIN1 | chr19:9835276 C>T | 5'Flank (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- PLA2G2F | c.-51G>A | 5'UTR (SNP) | VAF 10/67 reads (15%) | catalogued as rs111426554; called by muse, mutect2, varscan2
- POLR1C | c.382+42C>G | Intron (SNP) | VAF 77/300 reads (26%) | called by muse, mutect2, varscan2
- PPP5C | c.634-44G>T | Intron (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- PTPRD | c.541+144G>C | Intron (SNP) | VAF 33/194 reads (17%) | called by muse, mutect2, varscan2
- RHOT1 | chr17:32142407 G>A | 5'Flank (SNP) | VAF 5/31 reads (16%) | called by muse, varscan2
- RN7SL759P | chr15:20572628 G>T | 3'Flank (SNP) | VAF 85/681 reads (12%) | called by muse, mutect2, varscan2
- SERPINB10 | c.-27C>A | 5'UTR (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- SERPINB10 | c.-26C>T | 5'UTR (SNP) | VAF 14/115 reads (12%) | catalogued as rs1257393173; called by muse, mutect2, varscan2
- SF3B4 | c.-10C>G | 5'UTR (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- SLC24A1 | c.2054-20A>G | Intron (SNP) | VAF 65/254 reads (26%) | called by muse, mutect2, varscan2
- SORBS2 | c.-46+1415dup | Intron (INS) | VAF 18/120 reads (15%) | called by mutect2, pindel, varscan2
- TAF2 | c.*38G>A | 3'UTR (SNP) | VAF 17/233 reads (7%) | catalogued as COSV100978692; called by muse, mutect2
- TCP10L3 | n.500A>T | RNA (SNP) | VAF 92/266 reads (35%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.952+105C>T | Intron (SNP) | VAF 27/251 reads (11%) | called by muse, mutect2
- TPM1 | c.851+41_851+52del | Intron (DEL) | VAF 32/311 reads (10%) | called by mutect2, pindel
- TRABD | c.*570C>G | 3'UTR (SNP) | VAF 20/140 reads (14%) | catalogued as rs779868824, COSV100326838; called by muse, mutect2, varscan2
- TRDN | c.484+1104G>A | Intron (SNP) | VAF 40/317 reads (13%) | catalogued as rs1310144412; called by muse, mutect2, varscan2
- TTN | c.34264+618del | Intron (DEL) | VAF 44/327 reads (13%) | called by mutect2, pindel, varscan2
- USP4 | c.696-5593T>C | Intron (SNP) | VAF 54/221 reads (24%) | called by muse, mutect2, varscan2
- Unknown | chr21:16194376 C>T | IGR (SNP) | VAF 18/147 reads (12%) | catalogued as rs1327156879; called by muse, mutect2, varscan2
- Y_RNA | chr1:31507476 G>C | 5'Flank (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2
- ZBTB38 | c.-98-12146C>T | Intron (SNP) | VAF 17/165 reads (10%) | catalogued as rs1201902707; called by muse, mutect2, varscan2
- ZNF521 | c.-24C>G | 5'UTR (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- ZNF849P | n.87G>T | RNA (SNP) | VAF 14/130 reads (11%) | called by muse, varscan2
